Somatic mutation profile of tumor specimen TCGA-CE-A3MD-01A (aliquot TCGA-CE-A3MD-01A-11D-A20C-08) from TCGA case TCGA-CE-A3MD, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 31.2 years (11,399 days).
Specimen TCGA-CE-A3MD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1443216e-40e8-403a-be1c-df6944d6e84a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CE-A3MD-10A (Blood Derived Normal), aliquot TCGA-CE-A3MD-10A-01D-A20C-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e6de52b1-cc35-4b1b-87a8-7c50cbeea13b

The open-access MAF lists 8 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 6, Nonsense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS8 | c.2165G>A p.S722N | Missense Mutation (SNP) | VAF 113/277 reads (41%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.771); catalogued as rs367590895; called by muse, mutect2, varscan2
- ARSI | c.1605G>T p.R535S | Missense Mutation (SNP) | VAF 130/326 reads (40%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0); catalogued as COSV60817400; called by muse, mutect2, varscan2
- DNAH8 | c.2519C>G p.A840G | Missense Mutation (SNP) | VAF 33/108 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV59444394; called by muse, mutect2, varscan2
- ERC1 | c.1567G>T p.E523* (on ENST00000360905 / NM_178040.4; = p.E495* on NM_178039.4) | Nonsense Mutation (SNP) | VAF 58/199 reads (29%) | catalogued as COSV61694831; called by muse, mutect2, varscan2
- GOLGB1 | c.8216C>T p.S2739F | Missense Mutation (SNP) | VAF 8/204 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1450344663, COSV61465701; called by muse, mutect2
- OR4N5 | c.702C>A p.S234R | Missense Mutation (SNP) | VAF 67/252 reads (27%) | SIFT tolerated (0.96); PolyPhen benign (0.101); catalogued as COSV61320526; called by muse, mutect2, varscan2
- TG | c.3917G>C p.C1306S | Missense Mutation (SNP) | VAF 53/132 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.241); catalogued as COSV55075850; called by muse, mutect2, varscan2
- NOX5 | c.1443C>A p.I481= | Silent (SNP) | VAF 122/380 reads (32%) | catalogued as COSV52988729; called by muse, mutect2, varscan2
